Gene-level copy-number profile of tumor specimen ALCH-B40K-TTP1-A from ALCHEMIST case ALCH-B40K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.2 years (20,899 days).
Specimen ALCH-B40K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b248107-11e9-44a7-b025-350f4628a8b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B40K-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/65b66325-a993-44ec-9088-5cd54417572a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 8,750; copy number 2: 31,940; copy number 3: 15,809; copy number 4: 1,762; copy number 5: 39; copy number 6: 3; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,324,756–1,335,314, 2 genes (within-gene range 0–2): CPTP, TAS1R3.
- chr1:1,339,650–1,339,708, 1 gene (within-gene range 0–2): MIR6808.
- chr1:16,035,178–16,040,029, 1 gene: AL355994.2.
- chr2:128,236,716–128,350,927, 2 genes: HS6ST1, Y_RNA.
- chr2:232,520,388–232,536,667, 2 genes: PRSS56, CHRND.
- chr2:242,047,695–242,084,233, 1 gene (within-gene range 0–1): LINC01880.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:9,483,718–9,498,066, 2 genes: OR7E85P, UNC93B7.
- chr5:659,862–693,352, 2 genes (within-gene range 0–3): TPPP, AC026740.1.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:129,770,383–129,775,014, 3 genes: MIR182, MIR96, MIR183.
- chr7:149,262,171–149,297,312, 3 genes (within-gene range 0–2): ZNF783, AC004890.3, AC004890.2.
- chr12:66,767–182,399, 5 genes (within-gene range 0–2): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3.
- chr15:25,174,927–25,245,559, 39 genes (within-gene range 0–1): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41.
- chr15:74,173,710–74,176,872, 1 gene (within-gene range 0–2): ISLR.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr18:3,377,916–4,459,458, 21 genes: RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27.
- chr21:45,478,266–45,478,326, 1 gene (within-gene range 0–3): MIR6815.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,891,471–1,917,296, 2 genes, copy number 5: AL109917.1, CALML6.
- chr2:242,087,351–242,088,457, 1 gene, copy number 5: AC093642.2.
- chr15:21,293,653–21,951,323, 39 genes, copy number 5–6 (within-gene range 5–7): AC068446.1, AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr21:44,107,373–44,131,181, 1 gene, copy number 11: PWP2.

Autosomal genes at a single copy (total copy number 1): 6,509. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
